Somatic mutation profile of tumor specimen MP2PRT-PARMVN-TMP1-A (aliquot MP2PRT-PARMVN-TMP1-A-1-0-D-A80I-36) from MP2PRT case MP2PRT-PARMVN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 3.3 years (1,211 days).
Specimen MP2PRT-PARMVN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ec39478-397b-4a53-bafe-199b962c48bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARMVN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARMVN-NB1-A-1-0-D-A80I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5771382-25a7-4779-bdeb-8c9743b57d4d

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDNF | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 198/462 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as rs145772897; called by muse, mutect2, varscan2
- DIS3L | c.1180G>A p.V394M (on ENST00000319212 / NM_001143688.3; = p.V311M on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 115/275 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs199915796; called by muse, mutect2, varscan2
- LRP2 | c.12421G>A p.V4141I | Missense Mutation (SNP) | VAF 78/433 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs150382715, COSV99789745; called by muse, mutect2, varscan2
- PARD6A | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 104/497 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.932); catalogued as rs555623024; called by muse, varscan2
- ZC3H12C | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 71/393 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370069822; called by muse, mutect2, varscan2
- CHSY3 | c.1208A>T p.Y403F | Missense Mutation (SNP) | VAF 275/567 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- CNTNAP2 | c.2136C>T p.N712= | Silent (SNP) | VAF 239/493 reads (48%) | catalogued as rs187552025, COSV62144713, COSV62177655; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- PTCHD3 | c.63G>A p.P21= | Silent (SNP) | VAF 280/636 reads (44%) | catalogued as rs754966715, COSV71257312; called by muse, mutect2, varscan2
